Somatic mutation profile of tumor specimen TCGA-QH-A6X3-01A (aliquot TCGA-QH-A6X3-01A-21D-A32B-08) from TCGA case TCGA-QH-A6X3, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 27.9 years (10,184 days).
Specimen TCGA-QH-A6X3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4577362a-a2c2-4503-a6d2-1bc60a95b181.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QH-A6X3-10B (Blood Derived Normal), aliquot TCGA-QH-A6X3-10B-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a1b8ab6-5b88-4715-94fc-4d8f27f9eaa8

The open-access MAF lists 15 somatic variants for this specimen: 15 protein-altering or splice-affecting.
By variant classification: Missense Mutation 12, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 25/58 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAM7 | c.323T>C p.F108S | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99445046; called by muse, varscan2
- ARHGAP27 | c.1748G>A p.R583Q (on ENST00000428638 / NM_001282290.1; = p.R242Q on NM_199282.3) | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.207); catalogued as rs1483312373, COSV65357118; called by muse, mutect2, varscan2
- CNOT11 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as rs773000440, COSV99179383; called by muse, mutect2, varscan2
- DLGAP1 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV100233607; called by muse, mutect2, varscan2
- KCNA1 | c.626C>T p.T209M | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); catalogued as rs1565433235, COSV66836415; called by muse, mutect2, varscan2
- KLHL1 | c.1999C>A p.L667M | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.91); catalogued as COSV100918132; called by muse, mutect2, varscan2
- LIPI | c.804A>T p.Q268H | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs750775979, COSV100754012; called by muse, mutect2, varscan2
- MYO3B | c.2494T>C p.F832L | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100511715; called by muse, mutect2
- MYO7A | c.4003G>A p.A1335T | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.368); catalogued as rs375066152, COSV101289083; called by muse, mutect2, varscan2
- NEDD4 | c.2566C>T p.P856S (on ENST00000508342 / NM_001284338.1; = p.P437S on NM_006154.4) | Missense Mutation (SNP) | VAF 19/292 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.47); catalogued as COSV100164115; called by muse, mutect2
- NIBAN2 | c.100G>C p.D34H | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as COSV100964945; called by muse, mutect2
- TP53 | c.364_368del p.V122Lfs*25 | Frame Shift Del (DEL) | VAF 63/77 reads (82%) | called by mutect2, pindel, varscan2
- TRIM3 | c.122_124del p.F41del | In Frame Del (DEL) | VAF 8/94 reads (9%) | called by mutect2, pindel
- WWP2 | c.310_311del p.S104Qfs*43 | Frame Shift Del (DEL) | VAF 21/76 reads (28%) | called by pindel, varscan2
